FM case AD670 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/bfc554d4-42a6-4ace-a840-0a0c7a40ab5f

Female, 55.3 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the head, face or neck. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
